Somatic mutation profile of cancer-model specimen HCM-WCMC-0950-C67-85A (3D Organoid; aliquot HCM-WCMC-0950-C67-85A-01D-A88H-36), derived from the primary tumor of HCMI case HCM-WCMC-0950-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma, non-invasive; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 63.0 years (23,007 days).
Specimen HCM-WCMC-0950-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12a5e683-0cd2-41f5-9d47-c7f51dc0ab6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0950-C67-10A (Blood Derived Normal), aliquot HCM-WCMC-0950-C67-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58da82f6-9a00-466d-badd-a4ed6d988949

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ2 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 260/599 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs796052621, CX057284, COSV60437358; ClinVar: pathogenic; called by muse, varscan2
- IGLV3-1 | c.9G>T p.W3C | Missense Mutation (SNP) | VAF 160/343 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KMT2D | c.395del p.P132Lfs*76 | Frame Shift Del (DEL) | VAF 132/296 reads (45%) | called by mutect2, pindel, varscan2
- LHX5 | c.1058_1069del p.P353_G356del | In Frame Del (DEL) | VAF 47/266 reads (18%) | called by pindel, varscan2*
- MUC5AC | c.1020C>G p.N340K | Missense Mutation (SNP) | VAF 191/412 reads (46%) | SIFT tolerated (0.31); called by muse, mutect2, varscan2
- OR8B12 | c.799C>T p.L267F | Missense Mutation (SNP) | VAF 154/328 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- PIGT | c.1388G>T p.G463V | Missense Mutation (SNP) | VAF 136/323 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNLIP | c.445G>T p.V149F | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by mutect2, varscan2
- PYROXD1 | c.1229A>C p.H410P | Missense Mutation (SNP) | VAF 130/262 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HYDIN | c.14061T>C p.Y4687= | Silent (SNP) | VAF 157/450 reads (35%) | called by muse, mutect2, varscan2
- PDIA3 | c.1359A>T p.I453= | Silent (SNP) | VAF 103/226 reads (46%) | called by muse, mutect2, varscan2
- SMIM29 | c.162C>G p.L54= (on ENST00000394990 / NM_001008704.3; = p.L74= on NM_178508.5) | Silent (SNP) | VAF 150/322 reads (47%) | catalogued as rs748651817; called by muse, mutect2, varscan2
